CCDI case PBCDBX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/053f653a-c4ad-4ecb-85d2-8a208211292a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 15.6 years (5,698 days).

Biospecimens (3 samples)
- Sample 0DPH9Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHA5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPHAD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
